Gene-level copy-number profile of tumor specimen RC-B6E6-TTP1-A from RC case RC-B6E6, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Alive; Primary diagnosis: Peripheral T-cell lymphoma, NOS; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 56.8 years (20,761 days).
Specimen RC-B6E6-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f585c765-d708-4e60-9fd2-9ffdac05c837.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B6E6-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/fbc9ae4b-f60a-499f-b28b-44d10889b87c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 206; copy number 1: 5,565; copy number 2: 49,458; copy number 3: 3,685.

Homozygous deletions (total copy number 0; autosomes only): 206 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,544,550–158,554,405, 1 gene: OR6Y1.
- chr2:241,687,085–241,873,823, 12 genes: ING5, AC114730.3, D2HGDH, AC114730.1, AC114730.2, GAL3ST2, AC131097.1, AC131097.2, NEU4, AC131097.3, PDCD1, RTP5.
- chr2:241,893,988–241,902,551, 1 gene (within-gene range 0–1): FAM240C.
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:142,380,806–142,408,136, 7 genes: TRBV6-4, TRBV7-3, TRBV8-2, TRBV5-3, TRBV9, TRBV10-1, TRBV11-1.
- chr7:142,507,382–142,802,748, 50 genes (within-gene range 0–2): TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr14:21,887,857–22,552,156, 115 genes (within-gene range 0–2) (broad region; genes not listed).
- chr17:20,716,481–20,771,427, 3 genes: AC087499.2, RNFT1P3, HNRNPA1P19.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,221. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
